TARGET case TARGET-20-PAYKGB-Sorted-CD34neg-Lymphoid — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/65c50c76-7b21-4e19-9ff8-90daf0da7eb6

Biospecimens (1 sample)
- Sample TARGET-20-PAYKGB-Sorted-CD34neg-Lymphoid-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
